FM case AD14593 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/5129c771-f6fe-4adb-bf9b-d6fe4d3265f2

Male, 28.9 years: Melanoma, NOS (ICD-O-3 8720/3) of the skin; metastasis. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
